Somatic mutation profile of tumor specimen BA2144D (aliquot aq-BA2144D) from BEATAML1.0 case 2028, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.4 years (20,588 days).
Specimen BA2144D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9ec50a8-f757-4fdb-9ec0-9f804256547f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2486D (Solid Tissue Normal), aliquot aq-BA2486D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d604267e-b6f8-4172-a513-774dd7647c0a

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 4, Intron 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 70/170 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by mutect2, varscan2
- ASXL1 | c.1801A>G p.T601A | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs1298915538; called by muse, mutect2, varscan2
- CELSR2 | c.3919G>A p.E1307K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54768304; called by muse, mutect2
- FAM133A | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.886); catalogued as COSV59075664, COSV59076133; called by muse, varscan2
- GEMIN8 | c.169C>G p.P57A | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs1435593870; called by muse, mutect2
- MUC4 | c.9310C>T p.P3104S | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.65); catalogued as rs79083745, COSV57765101; called by muse, varscan2
- NLRP13 | c.2762G>A p.R921H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs778714175; called by muse, varscan2
- ROR1 | c.1624G>A p.V542I | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.544); catalogued as rs139362871, COSV64293813; called by muse, mutect2, varscan2
- RYR1 | c.12536G>A p.R4179H | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs564867337, CM108389, COSV62100755; called by muse, mutect2, varscan2
- TBC1D12 | c.1891A>G p.M631V | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.78); catalogued as COSV99831276; called by muse, mutect2, varscan2
- ZEB2 | c.3113A>G p.H1038R | Missense Mutation (SNP) | VAF 101/258 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57953045; called by muse, mutect2, varscan2
- AFAP1 | c.1295G>T p.W432L | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARID1A | c.6642C>A p.S2214R | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.241); called by muse, mutect2
- CWC22 | c.799_804+12del p.X267_splice | Splice Site (DEL) | VAF 44/92 reads (48%) | called by mutect2, varscan2
- ITGB2 | c.1679G>T p.C560F (on ENST00000302347; = p.C536F on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PIK3AP1 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, varscan2
- RDH8 | c.757C>A p.Q253K (on ENST00000651512; = p.Q233K on NM_015725.4) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- STARD4 | c.37A>G p.K13E | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UXS1 | c.276G>A p.L92= | Splice Region (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- WDR44 | c.740C>A p.P247H | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBLN4 | c.60G>T p.L20= | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- FAM98A | c.1521T>C p.H507= | Silent (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- KCND3 | c.648G>T p.L216= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as rs937971501; called by muse, mutect2
- RANBP17 | c.1605C>T p.T535= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as rs959690504; called by muse, mutect2, varscan2
- GALE | c.989-18C>T | Intron (SNP) | VAF 64/139 reads (46%) | catalogued as rs1164353657; called by muse, varscan2
